Surgical pathology report (de-identified scan), TCGA case TCGA-36-2542, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2542-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

TCGA - 36 - 2542

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

- A. Omentum: metastatic high-grade serous carcinoma
- B. Cul-de-sac mass: high-grade serous carcinoma (see comment)
- C. Pelvic tumour: high-grade serous carcinoma (see comment)
- D. Uterus, tubes, and ovaries:
- 1. high-grade serous carcinoma involving both ovaries and uterine serosa; the largest mass replaces the left ovary, which is the likely primary site
- 2. inactive endometrium, submucosal leiomyoma, adenomyosis
- 3. endometriosis of cul-de-sac
- 4. unremarkable cervix
- E. Pelvic tumour: high-grade serous carcinoma (see comment)
- F. Peritoneal washings: positive for serous carcinoma

Comment: It is difficult to determine from histological examination if the tumour in specimens B, C, and E are metastatic from the main tumour in the left ovary or became detached from it pre- or intraoperatively.

Clinical History as Provided by Submitting Physician:
See

[page 2 of 3]
██████████ with ascites complex pelvic mass

- A. Omentum
- B. Cul-de-sac mass
- C. Pelvic tumor
- D. Uterus, cervix, tubes and ovaries
- E. Pelvic tumor

Specimens Received:

- A: omentum
- B: cul de sac
- C: pelvic tumour
- D: uterus, cervix, tubes + ovaries
- E: pelvic tumour

Gross Description:

The specimen is received in five containers each labelled with the patient's name.

Container A is labelled OMENTUM and consists of a piece of omental tissue measuring 28 x 5 x 1 cm. There are multiple, small, solid nodules present on the surface of the omentum, the largest measuring 1.4 cm in greatest dimension. Representative sections are submitted in cassettes A1-A4.

Container B is labelled CUL-DE-SAC MASS and consists of a 375 g tumor mass that measures 10 x 8 x 7 cm. The surface is variegated with smooth and roughened areas. Serial sectioning of the tumor reveals a mostly solid mass with light-tan/creamy-coloured cut surface. No obvious necrosis or hemorrhage is noted. Focal small cystic areas contain gelatinous material. Several roughened surface areas are inked black, and the representative sections are submitted in cassette B1-B10.

Container C is labelled PELVIC TUMOR and consists of multiple fragments of tumor mass measuring 9 x 8 x 2 cm in aggregate. The largest fragment measures 6 x 3 x 0.8 cm. Representative sections are submitted in cassettes C1-C4.

Container D is labelled UTERUS, CERVIX, TUBES AND OVARIES and consists of a total hysterectomy and a bilateral salpingo-oophorectomy specimen. The specimen weighs 135 g. The uterus measures 4 cm (cornu to cornu) x 8.5 cm (fundus to ectocervix) x 3.5 cm (anterior to posterior). There are multiple small nodules present on the uterine serosal surface. The largest nodule measures 2.5 cm in greatest dimension and is present on the anterior serosal surface. The ectocervix is covered by smooth mucosa. Opening of the uterus reveals a patent endocervical canal and a firm, well-circumscribed nodule protruding subserosally measuring 1.5 cm in diameter. This nodule is lined by smooth endometrial surface. The rest of the endometrium and myometrium is unremarkable. The myometrium measures up to 1.4 cm in thickness. Representative sections are submitted as follows:

[page 3 of 3]
D1 -anterior cervix
D2 -posterior cervix
D3 -cul-de-sac
D4-D5 -anterior endometrium with subserosal nodule
D6-D7 -posterior endometrium
D8 -anterior serosal surface nodule

The left adnexal area has a large tumor mass measuring up to 5 cm in greatest dimension. This tumor has a roughened surface in some areas. The normal ovary is not grossly identified within the left adnexa. A segment of fallopian tube, mostly the distal portion, is present. This segment measures 4.5 cm in length and up to 0.4 cm in diameter. A fimbriated end is present at the distal end. Serial sectioning of the tumor mass reveals mostly white, solid, cut surface. Representative sections of the left adnexa are submitted as follows:

D9-D13 -tumor mass
D14 -tumor mass with fallopian tube
D15-D16 -fallopian tube

The right fallopian tube measures 6 cm in length and up to 0.4 cm in diameter and has a roughened, dark-brown surface in some areas. Otherwise the fallopian tube is grossly normal. The right ovary measures 2.5 x 1 x 0.8 cm with two nodules present on the ovarian surface, the larger one measures up to 1.5 cm in greatest dimension, and the small one measures 0.6 cm in greatest dimension. The larger one appears roughened on the surface. Representative sections are submitted as follows:

D17-D18 -ovary and the ovarian surface nodule
D19-D20 -right fallopian tube

Container E is labelled PELVIC TUMOR and consists of a 5 x 4 x 3 cm tumor mass with a roughened surface. Serial sectioning of the tumor mass reveals mostly solid cut surface. Representative sections are submitted in cassettes E1-E4.

Source: NCI Genomic Data Commons file 1558a638-d561-4dd5-9cef-a05951186b3c (TCGA-36-2542.F901ACCB-A3BE-461F-B145-39B83C201293.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).